Somatic mutation profile of tumor specimen TCGA-IG-A3Y9-01A (aliquot TCGA-IG-A3Y9-01A-12D-A247-09) from TCGA case TCGA-IG-A3Y9, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.1 years (26,330 days).
Specimen TCGA-IG-A3Y9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 010ab989-ee6b-4c9e-979f-e60ca08a00c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A3Y9-10A (Blood Derived Normal), aliquot TCGA-IG-A3Y9-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ac26d95-3844-4098-8246-6c62ab4f8c85

The open-access MAF lists 225 somatic variants for this specimen: 165 protein-altering or splice-affecting, 52 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 52, Nonsense Mutation 12, RNA 3, 3'Flank 2, Intron 2, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as rs775156203, COSV55588324; called by mutect2, varscan2
- ADPGK | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs748487995; called by muse, mutect2, varscan2
- AHDC1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.056); catalogued as COSV99899071; called by muse, mutect2
- ARMC9 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.185); catalogued as COSV63022349; called by muse, mutect2, varscan2
- ATR | c.5059G>C p.D1687H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63386321; called by muse, mutect2
- B3GALT4 | c.1131G>C p.Q377H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101005655; called by muse, mutect2
- BRCA2 | c.9160C>T p.P3054S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs786204070; ClinVar: uncertain significance; called by muse, mutect2
- BRD1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.574); catalogued as rs753681600; called by muse, varscan2
- BTBD6 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.11); catalogued as COSV100526743; called by muse, mutect2, varscan2
- C17orf78 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs1013032592; called by muse, mutect2, varscan2
- CANT1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV56606010; called by muse, mutect2, varscan2
- CCIN | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs1355646005, COSV100631941; called by muse, mutect2
- CCN5 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV51938248; called by muse, mutect2, varscan2
- CDCA2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs773590003, COSV57945676; called by mutect2, varscan2
- CDH18 | c.2314C>A p.P772T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56905633; called by muse, mutect2, varscan2
- CDH23 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV56490181; called by muse, mutect2, varscan2
- CHRDL2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs201003334; called by muse, mutect2
- CHST12 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs955669873, COSV51675059; called by muse, mutect2
- COL4A6 | c.5039G>A p.R1680Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs773301536; called by muse, varscan2
- COPA | c.1812C>G p.I604M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs1403560888; called by muse, mutect2
- DBX2 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as rs753569578; called by muse, mutect2, varscan2
- DDX3X | c.1969G>C p.D657H (on ENST00000399959; = p.D658H on NM_001356.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67864405; called by mutect2, varscan2
- DHTKD1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as COSV53806255; called by muse, mutect2
- DIAPH2 | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs763576938, COSV61281679; called by muse, mutect2, varscan2
- DIDO1 | c.6566G>A p.R2189Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.774); catalogued as rs768093655; called by muse, mutect2, varscan2
- DNAAF1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57578779; called by muse, mutect2, varscan2
- DOCK9 | c.2119C>G p.P707A (on ENST00000376460 / NM_001366676.2; = p.P708A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59637977; called by muse, mutect2, varscan2
- DSCAML1 | c.5447C>G p.S1816C (on ENST00000321322; = p.S1756C on NM_020693.4) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100355442; called by muse, mutect2, varscan2
- DST | c.22103G>C p.R7368T (on ENST00000361203 / NM_001374722.1; = p.R5078T on NM_015548.5) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as COSV55011551; called by muse, mutect2
- ELFN2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs762221074; called by muse, mutect2, varscan2
- FAF2 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.814); catalogued as COSV56129609; called by muse, mutect2
- GPR26 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52935911; called by muse, mutect2, varscan2
- HSD11B2 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1139495, COSV99340979; called by muse, varscan2
- ICAM5 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99321261; called by muse, mutect2
- INTS2 | c.2800C>G p.Q934E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99248546; called by muse, mutect2
- KALRN | c.2376G>C p.L792F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779442681; called by muse, mutect2
- KMT2A | c.8447C>G p.S2816C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV63289163; called by muse, mutect2
- KMT2C | c.10882G>A p.D3628N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51461317; called by muse, mutect2, varscan2
- KRT28 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.357); catalogued as rs1172756200; called by muse, mutect2
- KRT9 | c.1745G>A p.S582N | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs775942442; called by muse, mutect2, varscan2
- LAMA4 | c.4447G>C p.E1483Q (on ENST00000230538 / NM_001105206.3; = p.E1476Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV100037449, COSV100037828; called by muse, mutect2, varscan2
- LAMA4 | c.1222G>A p.E408K (on ENST00000230538 / NM_001105206.3; = p.E401K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV57897257; called by muse, mutect2
- LRRTM4 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297404, COSV69139923; called by muse, mutect2, varscan2
- LSM14B | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV53383821; called by muse, mutect2, varscan2
- MAP3K11 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs764566604; called by muse, mutect2, varscan2
- MUC16 | c.7190C>G p.S2397* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV67476394; called by muse, mutect2, varscan2
- NIPBL | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as rs1309013213; called by mutect2, varscan2
- NPAS3 | c.526G>A p.E176K (on ENST00000356141 / NM_001164749.2; = p.E144K on NM_022123.3) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58073552; called by muse, mutect2, varscan2
- P2RY4 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as rs775969220, COSV65736719; called by muse, mutect2, varscan2
- PCDHA2 | c.50C>G p.S17W | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs781893367, COSV100973646; called by muse, mutect2, varscan2
- PCDHB6 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1554277570; called by muse, mutect2, varscan2
- PCDHB9 | c.1514C>G p.S505C | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53376867; called by muse, mutect2, varscan2
- PCED1A | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV62313641; called by muse, mutect2, varscan2
- PEAK1 | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766575004; called by muse, mutect2, varscan2
- PLEKHA6 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs771389862, COSV99692742; called by muse, mutect2, varscan2
- PLXND1 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60715567; called by muse, mutect2
- PODN | c.1457C>T p.S486L (on ENST00000395871; = p.S438L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1557656592, COSV57014967; called by muse, mutect2
- PTBP1 | c.947C>T p.A316V (on ENST00000349038 / NM_031991.4; = p.A342V on NM_002819.5) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1324568910; called by muse, mutect2, varscan2
- RECK | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100937464; called by muse, mutect2, varscan2
- RFPL2 | c.703C>G p.R235G | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV99964399; called by muse, mutect2
- RILP | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as rs755684887; called by muse, mutect2
- RPE65 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52012809; called by muse, mutect2
- RUSC2 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs765030082; called by muse, varscan2
- SAMD4A | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs988622753, COSV51878773; called by muse, mutect2
- SCG2 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV59541284; called by muse, mutect2, varscan2
- SERPINA4 | c.704T>A p.V235D | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1202052381; called by muse, mutect2, varscan2
- SIPA1L1 | c.1208G>C p.G403A | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1174369385; called by muse, mutect2, varscan2
- SLC16A2 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV52084898, COSV99330994; called by muse, mutect2
- SLC44A4 | c.1607G>C p.C536S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV99998520; called by muse, mutect2, varscan2
- SLCO2A1 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM133644; called by muse, mutect2, varscan2
- SMG1 | c.10709C>T p.S3570L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV101247055; called by muse, mutect2, varscan2
- SMN2 | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV101058587; called by mutect2, varscan2
- SRSF7 | c.653C>G p.P218R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs771774999; called by muse, mutect2, varscan2
- STARD3NL | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.472); catalogued as COSV50518313; called by muse, mutect2, varscan2
- SYNE2 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs1403336820, COSV59939044; called by muse, mutect2, varscan2
- TMEM209 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as COSV61023468; called by muse, mutect2, varscan2
- UNC5C | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767605519, COSV71658457; called by mutect2, varscan2
- UPF1 | c.2530G>A p.E844K (on ENST00000599848 / NM_001297549.2; = p.E833K on NM_002911.4) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53197341; called by muse, varscan2
- ZNF148 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV62301854; called by muse, mutect2
- ZNF213 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1169722463; called by muse, mutect2
- ZNF420 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as rs1329126856; called by muse, mutect2
- ACAN | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAT2 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AIMP1 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- AMOT | c.1321C>T p.L441F (on ENST00000371959 / NM_001113490.1; = p.L32F on NM_133265.3) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APLP2 | c.2172C>G p.I724M | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASB12 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, varscan2
- ATP6V1D | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- BEND2 | c.689T>G p.F230C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- BEND3 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- BOP1 | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2
- BPGM | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2
- BRWD3 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC50 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDC37L1 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKN1A | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.268); called by muse, mutect2
- CEP290 | c.4158C>G p.I1386M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHGB | c.1585C>G p.L529V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CLTCL1 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COBLL1 | c.1130G>C p.R377T (on ENST00000392717; = p.R339T on NM_014900.5) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CSAG2 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DDX39A | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2
- DNAH17 | c.12618G>C p.E4206D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DNAH7 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM71D | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FAM9B | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FCSK | c.3024G>C p.M1008I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- GPT2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- GRK3 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HECTD4 | c.1961A>T p.N654I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2
- HPS5 | c.464_465del p.S155* (on ENST00000349215 / NM_181507.2; = p.S41* on NM_007216.4) | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel
- IFI27L2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2
- IPP | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- KCTD16 | c.88A>C p.N30H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KERA | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2
- KLHL20 | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBNL1 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.311); called by muse, mutect2
- MDN1 | c.10082C>G p.S3361C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ME1 | c.951G>C p.L317F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- MEA1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- MYH4 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- NAV3 | c.5082G>C p.K1694N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- NOL10 | c.726G>C p.L242F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOTCH1 | c.2777dup p.N927Qfs*17 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- OR4C15 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OSBPL6 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.575); called by muse, mutect2
- PCDHB1 | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCIF1 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PDS5B | c.2989C>G p.H997D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHLDB3 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHM2 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- POLR3A | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPIP5K2 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- REG1A | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- RGL3 | c.1688G>C p.R563T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RTKN | c.319G>C p.D107H (on ENST00000272430 / NM_001015055.2; = p.D94H on NM_033046.2) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- RYR2 | c.11015G>C p.S3672T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SETBP1 | c.2974C>T p.H992Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SLC13A4 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAPIN | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPATA22 | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- SPTA1 | c.6037C>G p.L2013V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.043); called by muse, mutect2
- STK31 | c.2361C>G p.D787E | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.15868G>C p.E5290Q (on ENST00000367255 / NM_182961.4; = p.E5219Q on NM_033071.3) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- SYNE2 | c.4102C>T p.H1368Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TBC1D19 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- TENT4B | c.1898C>T p.S633F (on ENST00000561678 / NM_001365323.2; = p.S618F on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- TEX2 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.093); called by muse, mutect2
- TGFB3 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIAM1 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- TRIM22 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- TTC21B | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TTN | c.97064C>A p.T32355K (on ENST00000591111; = p.T24931K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.6068C>G p.A2023G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- VPS13D | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- YAP1 | c.1097C>G p.S366C (on ENST00000282441 / NM_001130145.3; = p.S312C on NM_006106.5) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YWHAB | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ZMYM3 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF143 | c.1058_1060del p.G353del | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- ZNF311 | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- ZNF438 | c.638G>C p.S213T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ZNF518A | c.2288G>C p.R763T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ZNF804B | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ABCG5 | c.112C>T p.L38= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- ADGRE2 | c.1149G>C p.V383= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2
- ATP10B | c.108G>C p.G36= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV58780726; called by muse, mutect2
- CACNA1A | c.3450C>A p.V1150= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- CLPTM1 | c.207C>A p.I69= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs748937869; called by muse, mutect2, varscan2
- CSF2RB | c.792G>A p.V264= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- CYB5R2 | c.201G>A p.R67= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as rs1042667994; called by muse, mutect2
- DCC | c.3234G>A p.P1078= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs746957136, COSV71425277; called by muse, mutect2, varscan2
- DYNC1H1 | c.10360C>T p.L3454= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- EPM2AIP1 | c.1209C>G p.V403= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- FAM71C | c.720G>A p.E240= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV60944610; called by muse, mutect2
- FRMD6 | c.1296C>T p.S432= (on ENST00000344768 / NM_001267046.2; = p.S424= on NM_152330.4) | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- GINS2 | c.459C>T p.I153= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- GJA9 | c.1341C>T p.F447= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV62531859; called by muse, mutect2, varscan2
- GLIPR1L1 | c.9G>A p.L3= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV56884210; called by muse, mutect2, varscan2
- HSPA2 | c.1797G>A p.Q599= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- HTR3A | c.606C>T p.V202= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- INPP5K | c.96C>T p.L32= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ITGA8 | c.1098G>A p.V366= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV65233517; called by muse, mutect2, varscan2
- KCTD4 | c.426C>T p.F142= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- LRP1B | c.10470C>A p.P3490= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs752743011, COSV67201447; called by muse, mutect2, varscan2
- LZTS2 | c.87G>C p.V29= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100932303; called by muse, mutect2, varscan2
- MRAS | c.621C>T p.I207= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- MROH9 | c.964T>C p.L322= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- MYH13 | c.5523G>C p.L1841= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- OR4C15 | c.24A>G p.A8= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs1186852944, COSV58953656; called by muse, mutect2, varscan2
- OR5AK2 | c.60G>A p.Q20= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as rs775272882, COSV100475876, COSV58803628; called by muse, mutect2
- OTP | c.369C>T p.F123= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as rs1297067206, COSV60569878; called by muse, mutect2
- OXA1L | c.132T>C p.G44= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs764727247; called by muse, mutect2, varscan2
- PCCA | c.597C>G p.V199= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs879179350; called by muse, mutect2
- PDLIM3 | c.69C>T p.F23= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- PLBD1 | c.882C>T p.S294= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- PLEC | c.7716G>A p.E2572= (on ENST00000322810 / NM_201380.4; = p.E2462= on NM_000445.5) | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- PLXNA2 | c.327C>T p.L109= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- PSMG3 | c.84C>T p.F28= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- RRP15 | c.642G>A p.L214= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV65117600, COSV65118813; called by muse, mutect2
- RYR3 | c.9510C>T p.L3170= (on ENST00000389232; = p.L3171= on NM_001036.6) | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- SEMG2 | c.369T>C p.F123= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- SETDB1 | c.2304G>A p.K768= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3936C>T p.N1312= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs778116596, COSV55281226; called by muse, mutect2, varscan2
- SLC25A51 | c.216G>A p.L72= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV54254045; called by muse, mutect2, varscan2
- SLC9A4 | c.1845C>G p.L615= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- SLC9A5 | c.1536G>A p.L512= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- SPAG17 | c.2811C>G p.L937= | Silent (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- STX17 | c.261G>A p.L87= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- TDP1 | c.834C>T p.V278= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs377532827; called by muse, mutect2
- THEMIS2 | c.1365C>G p.V455= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- TTC30B | c.45C>T p.T15= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.80373G>A p.L26791= (on ENST00000591111; = p.L19367= on NM_003319.4) | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV59968113; called by muse, mutect2
- USP35 | c.9G>A p.K3= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV71572667, COSV71573187; called by muse, mutect2
- XIRP2 | c.3402A>G p.V1134= (on ENST00000628543; = p.V1309= on NM_152381.6) | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- ZNF700 | c.702C>T p.F234= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV54313986; called by muse, mutect2
- ATP2A3 | c.3068+240C>G | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CD300LD | chr17:74592610 T>A | 5'Flank (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- LONP2 | chr16:48361853 G>C | 3'Flank (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53525860; called by muse, mutect2, varscan2
- PDXK | c.88-1565G>C | Intron (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- SLC66A1L | n.272C>G | RNA (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2641G>A | RNA (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- TMEM105 | n.559C>G | RNA (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580926 A>G | 3'Flank (SNP) | VAF 6/55 reads (11%) | catalogued as rs1408044516; called by muse, mutect2, varscan2
